Gene-level copy-number profile of tumor specimen ALCH-B1HA-TTP1-A from ALCHEMIST case ALCH-B1HA, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 65.0 years (23,751 days).
Specimen ALCH-B1HA-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file ebdd45f3-bc15-4a80-8c88-8ca73e97b09c.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B1HA-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,248 have no estimate.
https://portal.gdc.cancer.gov/files/68443862-d495-4f66-ac09-ab320adb3082

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 6; copy number 1: 7,809; copy number 2: 48,407; copy number 3: 1,762; copy number 4: 137; copy number 5: 108; copy number 6: 83; copy number 7: 11; copy number 8: 4; copy number 9: 33; copy number 14: 12; copy number 17: 3.

Homozygous deletions (total copy number 0; autosomes only): 4 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:160,247,517–160,345,396, 4 genes (within-gene range 0–1): AC112191.1, CCNJL, AC112191.2, AC112191.3.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 254 genes in 8 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:55,078,481–55,313,924, 5 genes, copy number 6–8 (within-gene range 4–8): KDR, RN7SL822P, AC021220.1, RNU6-746P, LRRC34P2.
- chr8:127,578,473–128,564,679, 16 genes, copy number 7–17: AC104370.1, CASC11, MYC, PVT1, MIR1204, AC084123.1, TMEM75, MIR1205, RNVU1-32, MIR1206, AC103705.1, RNU4-25P, MIR1207, MIR1208, RN7SKP226, LINC00824.
- chr9:34,179,005–34,774,466, 35 genes, copy number 6: UBAP1, RPL35AP2, AL353662.2, RNA5SP282, AL353662.1, KIF24, RNU2-50P, SERPINH1P1, NUDT2, MYORG, C9orf24, Y_RNA, FAM219A, DNAI1, RN7SKP24, ENHO, AL160270.1, AL160270.2, CNTFR, CNTFR-AS1, RPP25L, DCTN3, ARID3C, SIGMAR1, GALT, AL162231.3, IL11RA, CCL27, AL162231.4, AL162231.1, AL162231.2, CCL19, AL162231.5, CCL21, FAM205A.
- chr9:63,581,254–63,581,834, 1 gene, copy number 5: AL591438.1.
- chr12:20,368,537–20,688,583, 1 gene, copy number 6 (within-gene range 1–6): PDE3A.
- chr12:20,551,590–23,188,807, 42 genes, copy number 6 (within-gene range 3–7): AC112777.1, SLCO1C1, SLCO1B3, SLCO1B3-SLCO1B7, AC011604.1, SLCO1B7, AC022335.1, SLCO1B1, SLCO1A2, IAPP, PYROXD1, ELOCP31, RECQL, GOLT1B, SPX, GYS2, AC010197.2, LDHB, AC010197.1, AC010185.1, KCNJ8, ABCC9, AC008250.1, AC008250.2, AC092862.1, CMAS, ST8SIA1, AC007671.1, SULT6B2P, RNU1-149P, AC087318.1, AC053513.1, C2CD5, AC053513.2, LRRC34P1, AC087241.1, AC087241.2, ETNK1, AC084816.1, RPS27P22, AC084819.1, AC087258.1.
- chr14:27,258,717–31,207,804, 53 genes, copy number 5: AL390334.1, LINC00645, MIR3171, BNIP3P1, AL139023.1, RPL26P3, LINC02300, EIF4A1P12, BTF3P2, FOXG1-AS1, AL049777.1, FOXG1, LINC01551, LINC02282, LINC02281, LINC02327, AL122126.1, LINC02326, Y_RNA, AL135878.1, RNU6-864P, AL133166.1, AL158058.1, AL158058.2, RNU11-5P, PRKD1, AL356756.1, RNU6-1234P, AL355053.1, AL133372.3, AL133372.2, AL133372.1, AL079305.1, G2E3-AS1, AL117355.1, SYF2P1, G2E3, SCFD1, UBE2CP1, AL121852.1, RPL12P5, AL049830.2, AL049830.1, COCH, AL049830.3, STRN3, HIGD1AP17, MIR624, AL049830.4, AP4S1, HECTD1, RPL21P5, RNU6-541P.
- chr14:35,085,467–41,604,988, 101 genes, copy number 5–14 (within-gene range 4–14) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 5,467. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
